Somatic mutation profile of tumor specimen TCGA-P5-A77X-01A (aliquot TCGA-P5-A77X-01A-11D-A32B-08) from TCGA case TCGA-P5-A77X, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 55.1 years (20,128 days).
Specimen TCGA-P5-A77X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f2acd84-bb1b-4019-a513-7715853ba8c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A77X-10A (Blood Derived Normal), aliquot TCGA-P5-A77X-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b15f1c3-447f-4d7e-88e7-bc9457a1b4d9

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Frame Shift Del 8, Silent 7, In Frame Del 2, Splice Site 1, Intron 1, Splice Region 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATP10B | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773040394, COSV100469313, COSV58778079; called by muse, mutect2, varscan2
- CFAP251 | c.2078G>T p.R693I | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV56614874, COSV99995985; called by muse, mutect2
- CFHR5 | c.1378A>G p.T460A | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99888432; called by muse, mutect2, varscan2
- COL6A2 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.772); catalogued as rs145450812, COSV100153315; called by muse, mutect2, varscan2
- ETNPPL | c.501G>C p.V167= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99625144; called by muse, varscan2
- EXOG | c.638_641del p.S213Tfs*3 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs771911750; called by pindel, varscan2
- IL1RAPL1 | c.458A>C p.K153T | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100146665; called by muse, mutect2
- LATS1 | c.2228_2230del p.L743del | In Frame Del (DEL) | VAF 20/122 reads (16%) | catalogued as rs753305883; called by pindel, varscan2
- NEK1 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV101455657; called by muse, mutect2, varscan2
- ODF2L | c.1184A>G p.E395G (on ENST00000317336; = p.E366G on NM_020729.3) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99644020; called by muse, mutect2, varscan2
- OLFM4 | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.011); catalogued as COSV99524276; called by muse, mutect2, varscan2
- PRUNE2 | c.4594G>A p.D1532N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.212); catalogued as COSV100944442; called by muse, mutect2, varscan2
- RHOT1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.41); catalogued as COSV100447113, COSV61713846; called by muse, mutect2, varscan2
- SLC30A6 | c.1361A>G p.N454S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.005); catalogued as COSV99249551; called by muse, mutect2
- TAS2R31 | c.677_678del p.K226Sfs*42 | Frame Shift Del (DEL) | VAF 34/160 reads (21%) | catalogued as rs767420668; called by pindel, varscan2
- TMEM86A | c.467T>G p.F156C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV99773665; called by muse, mutect2, varscan2
- WDR31 | c.908A>T p.D303V (on ENST00000374193 / NM_001006615.3; = p.D302V on NM_145241.5) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100516665; called by muse, mutect2, varscan2
- ZNF518B | c.2335A>G p.R779G | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100456648, COSV58721596; called by muse, mutect2, varscan2
- ADAT2 | c.61_63del p.E21del | In Frame Del (DEL) | VAF 38/200 reads (19%) | called by pindel, varscan2
- ATAD5 | c.4869_4872del p.K1623Nfs*23 | Frame Shift Del (DEL) | VAF 41/109 reads (38%) | called by mutect2, pindel, varscan2
- CIC | c.1486_1489del p.S496Lfs*2 | Frame Shift Del (DEL) | VAF 5/86 reads (6%) | called by mutect2, pindel*
- CIC | c.2624_2625del p.K875Sfs*55 | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | called by mutect2, pindel, varscan2
- CPLANE1 | c.8023_8026del p.L2675Cfs*22 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- FUBP1 | c.248_250+1del p.X83_splice | Splice Site (DEL) | VAF 16/30 reads (53%) | called by mutect2, pindel, varscan2
- MATK | c.48_49del p.C16* | Nonsense Mutation (DEL) | VAF 21/69 reads (30%) | called by pindel, varscan2
- PHLDA1 | c.457_461dup p.V155Rfs*85 | Frame Shift Ins (INS) | VAF 5/21 reads (24%) | called by mutect2, pindel
- USP28 | c.625_626del p.K209Efs*21 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.2261_2262del p.E754Gfs*28 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- CPZ | c.1371C>T p.S457= (on ENST00000360986 / NM_001014447.3; = p.S446= on NM_003652.3) | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as rs574133810, COSV100248905; called by muse, mutect2, varscan2
- CYP4F11 | c.333C>T p.T111= | Silent (SNP) | VAF 68/175 reads (39%) | catalogued as COSV99930792; called by muse, mutect2
- GUCY2F | c.99G>T p.L33= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV99484813; called by muse, mutect2, varscan2
- IKBKG | c.9G>A p.R3= | Silent (SNP) | VAF 13/221 reads (6%) | catalogued as COSV99682405; called by muse, mutect2
- LRP2 | c.11268C>T p.P3756= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV99787689; called by muse, mutect2, varscan2
- OR2M3 | c.300A>G p.Q100= | Silent (SNP) | VAF 36/349 reads (10%) | catalogued as COSV101513418, COSV71758923; called by muse, mutect2, varscan2
- SHROOM4 | c.1326G>T p.G442= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV99173255; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22294T>C | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as COSV101051012; called by muse, mutect2, varscan2
